Surgical pathology report (de-identified scan), TCGA case TCGA-W2-A7HA, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Medical College of Wisconsin, specimen TCGA-W2-A7HA-01B (Primary Tumor).

[page 1 of 2]
Results History

SURG PATH FINAL REPORT

Entry Information

Entry Date and Time

Lab Status
Final result

Entered by

Component Results

SURG PATH FINAL REPORT:

ICD-O-3
Pheochromocytoma NOS 8700/0
Site (R) Adrenal gland NOS
C74.9
JW 9/4/13

Accession #:

Specimen:

- A. Right adrenal
- B. Gallbladder

Clinical Notes:

Pheochromocytoma. Fresh tissue (specimen A) saved for tissue bank.

Diagnosis:

A. Right adrenal:

- Pheochromocytoma.

Note: the tumor is well-circumscribed and encapsulated. There is no evidence of infiltration of the capsule into the surrounding structures. There is no evidence of increased mitotic activity or tumor cell necrosis. There is one focus of vascular invasion noted (slide A6).

Clinical follow-up is recommended as histologic features may not always correlate well with biologic behavior.

B. Gallbladder:

- Chronic cholecystitis with cholesterosis.

(Electronically signed by)

Verified:

Gross:

A. The specimen is labeled "right adrenal." Received fresh in is a 96.0 gm, 7.0 x 6.5 x 4.5 cm adrenal gland with a scant amount of attached fibroadipose tissue. The adrenal appears well-encapsulated with a smooth tan-orange outer surface. The specimen is marked with black ink and serially sectioned to reveal the majority of the specimen composed of a well-circumscribed mass, 6.5 x 5.5 x 4.5 cm. The mass exhibits a soft red-tan hemorrhagic cut surface with a faint lobulated pattern. The mass is focally surrounded a thin rim of orange-tan cortical tissue. The

[page 2 of 2]
uninvolved adrenal exhibits a rim of cortical tissue with a central thin tan-brown medulla. Photos of overall and cut specimen are taken. Portions of the mass and unremarkable adrenal are submitted for tissue bank. Representative sections are submitted as follows:

Accession #:

Cassette Designation:

A1-7	Mass
A8	Mass with adjacent adrenal
A9	Unremarkable adrenal

B. The specimen is labeled "gallbladder." Received fresh and placed in formalin is an 8.0 x 3.5 x 1.5 cm intact gallbladder with a small amount of attached cystic duct, 0.4 cm in diameter. The serosa is smooth and pink-tan. The specimen is opened to reveal a lumen filled with brown-red bile. No stones are present. The mucosa is velvety and dark brown with diffuse yellow speckling. The wall thickness is 0.1 to 0.2 cm. Representative sections, including cystic duct margin, are submitted in cassette B.

Microscopic:

Histological examinations have been performed on specimens A and B.

Administrative Notes:

CPT:

No charge codes are associated with this case.

Entry Information

Entry Date and Time

Lab Status
In process

Entered by

Criteria	8/29/13	Yes	No

Source: NCI Genomic Data Commons file 4e17dd05-f7a6-499a-86d2-ea0037e39850 (TCGA-W2-A7HA.FD947970-B76A-4AD0-9308-9F30BBEB78A3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).